MMRF case MMRF_1107 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4319b1c8-927b-43d7-8c5b-63003292c841

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 118 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.1 years (29,995 days); ISS stage: III; Days to last known disease status: 118 days; Days to last follow up: 118 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 93 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 118.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 1): M Protein 1.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 3.46 g/L; Immunoglobulin A 31.2 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 6.65 µg/mL; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 4.24 mmol/L; C-Reactive Protein 5.05 mg/dL.
- Day 50 (ECOG 1): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.931 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 3.57 g/L; Immunoglobulin A 18.1 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 8.2 mmol/L.

Other clinical attributes
- Day -14: Weight: 78 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples)
- Sample MMRF_1107_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1107_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
